Somatic mutation profile of tumor specimen 0DL6S1 from CCDI case PBBYGA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pineoblastoma; Tissue or organ of origin: Pineal gland; Age at diagnosis: 11.5 years (4,207 days).
Specimen 0DL6S1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20feb94c-335e-4f68-bd09-1ae01937c0f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL6RF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5cb2295-bd6f-4fba-a4fe-eddcdce44418

The open-access MAF lists 26 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Intron 3, 3'UTR 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSPA4L | c.973A>G p.M325V | Missense Mutation (SNP) | VAF 565/1251 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs1392765211; called by muse, mutect2, varscan2
- NUP210L | c.808A>G p.I270V | Missense Mutation (SNP) | VAF 106/1054 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.09); catalogued as rs763325991; called by muse, mutect2
- PKD1L2 | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 85/773 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs371845680; called by muse, mutect2, varscan2
- PRRC2C | c.4103G>A p.R1368Q (on ENST00000367742; = p.R1366Q on NM_015172.4) | Missense Mutation (SNP) | VAF 88/804 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs779499618, COSV58903257; called by muse, mutect2, varscan2
- RNF214 | c.1414A>G p.M472V | Missense Mutation (SNP) | VAF 91/839 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372942701; called by muse, mutect2, varscan2
- TENM2 | c.7307G>A p.R2436Q (on ENST00000518659 / NM_001122679.2; = p.R2197Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 184/416 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs751139107, COSV101319401; called by muse, mutect2, varscan2
- WRN | c.3767C>G p.S1256* | Nonsense Mutation (SNP) | VAF 128/1107 reads (12%) | catalogued as CM154316; called by muse, mutect2, varscan2
- ANK2 | c.364A>T p.N122Y | Missense Mutation (SNP) | VAF 173/1239 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- EZH1 | c.761A>T p.K254M | Missense Mutation (SNP) | VAF 34/1022 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2
- F2RL3 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 22/597 reads (4%) | called by muse, mutect2
- FXR2 | c.1852G>T p.A618S | Missense Mutation (SNP) | VAF 107/1190 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.355); called by muse, mutect2
- GRAMD1C | c.1729C>A p.L577M | Missense Mutation (SNP) | VAF 86/1278 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.556); called by muse, mutect2
- KCNJ14 | c.779A>T p.D260V | Missense Mutation (SNP) | VAF 101/1010 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- UMODL1 | c.122T>C p.V41A | Missense Mutation (SNP) | VAF 78/726 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- ANK2 | c.363C>G p.A121= | Silent (SNP) | VAF 162/1191 reads (14%) | called by muse, varscan2
- CGRRF1 | c.900G>A p.K300= | Silent (SNP) | VAF 25/596 reads (4%) | catalogued as COSV53596514; called by muse, mutect2
- FAM98B | c.180A>G p.K60= | Silent (SNP) | VAF 102/886 reads (12%) | called by mutect2, varscan2
- KRTAP10-3 | c.624C>T p.S208= | Silent (SNP) | VAF 51/1271 reads (4%) | catalogued as rs781978201; called by muse, mutect2
- PDCD1 | c.564G>T p.L188= | Silent (SNP) | VAF 67/635 reads (11%) | called by muse, mutect2
- PTPRS | c.1899G>A p.T633= | Silent (SNP) | VAF 68/677 reads (10%) | catalogued as rs1339743173, COSV53628738; called by muse, mutect2, varscan2
- SOX10 | c.51G>A p.S17= | Silent (SNP) | VAF 55/367 reads (15%) | catalogued as rs1308432872; called by muse, mutect2, varscan2
- CST8 | c.*73G>T | 3'UTR (SNP) | VAF 24/326 reads (7%) | catalogued as rs1418541828; called by muse, mutect2
- ECHDC1 | c.434+46A>G | Intron (SNP) | VAF 22/662 reads (3%) | called by muse, mutect2
- EPG5 | c.4810-11A>G | Intron (SNP) | VAF 33/541 reads (6%) | catalogued as COSV56348435; called by muse, mutect2
- ZCCHC8 | c.605+47G>A | Intron (SNP) | VAF 35/639 reads (5%) | called by muse, mutect2
- ZNF346 | c.*7G>A | 3'UTR (SNP) | VAF 21/275 reads (8%) | called by muse, mutect2
